CPTAC case C3N-03450 — Brain — Gliomas (CPTAC-3)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of the Clinical Proteomic Tumor Analysis Consortium (CPTAC). Disease type: Gliomas; Primary site: Brain. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/27492b27-3a45-439c-8a9c-338a1eec302f

Demographics
Sex at birth: female; Race: white; Year of birth: 1939; Vital status: Dead; Days to death: 38 days; Cause of death: Cancer Related; Country of birth: Poland.

Diagnoses (1)
1. Glioblastoma: ICD-O-3 morphology code: 9440/3; Tissue or organ of origin: Brain, NOS; Site of resection or biopsy: Temporal lobe; Age at diagnosis: 78.8 years (28,780 days); Year of diagnosis: 2017; Last known disease status: With tumor; Days to last known disease status: 38 days; Progression or recurrence: no; Days to last follow up: 38 days.
   Pathology details: Greatest tumor dimension: 1 cm.
   Chemotherapy — whether it was given is not recorded by GDC; Treatment outcome: Persistent Disease.
   Radiation Therapy, NOS — whether it was given is not recorded by GDC; Treatment outcome: Persistent Disease.

Exposures
- Tobacco smoking status: Current Reformed Smoker, Duration Not Specified; Cigarettes per day: 20; Alcohol history: Yes; Alcohol intensity: Not Heavy Drinker; Secondhand smoke as child: Yes; Type of smoke exposure: Smoke exposure, NOS.

Biospecimens (1 sample)
- Sample C3N-03450-08: Sample type: Solid Tissue Normal; Tissue type: Normal; Specimen type: Solid Tissue; Biospecimen anatomic site: Brain; Biospecimen laterality: Left; Preservation method: Snap Frozen; Freezing method: LN2; Days to sample procurement: -19 days; Initial weight: 398 mg; Method of sample procurement: Surgical Resection; Diagnosis pathologically confirmed: Yes.
